Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5177, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5177-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA-BP-5177

Clinical Diagnosis & History:

with renal mass right side. Rule out renal cell carcinoma.

Specimens Submitted:

1: SP: Right kidney

DIAGNOSIS:

- 1) KIDNEY, RIGHT; NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL TYPE), NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS SOLID.
- THE TUMOR GREATEST DIAMETER IS 4.0 CM. ✓
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE. ✓

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled, "Right kidney". It consists of a 209 grams, 11.0 x 9.0 x 3.0 cm nephrectomy specimen with attached perinephric fat and 5.0 x 0.3 cm patent ureter. The vascular and ureteral margins are shaved and submitted. The specimen is bivalved to reveal a 4.0 x 3.2 x 2.4 cm heterogenous, yellow to gray-white circumscribed, cortically based mass. It does not extend through the capsule. The mass extends to the renal pelvis but does not infiltrate it grossly. The renal vein is not grossly involved by tumor. The remaining renal parenchyma is tan-red without grossly identifiable lesions. Representative sections are submitted. A fresh specimen is saved for TPS and photographs are also taken.

Summary of Sections:

M - vascular and ureteral margins

TC - tumor to capsule

TN - tumor to normal

TRP - tumor to renal pelvis

NK - normal kidney

U - random ureter

RP - representatives of pelvic fat

Summary of Sections:

Part 1: SP: Right kidney

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Block	Sect. Site	PCs
1	m	1
1	nk	1
2	rp	2
2	tc	2
2	tn	2
2	trp	2
1	u	1

Source: NCI Genomic Data Commons file 087303c0-3f3d-4a79-8741-549eb29e0e70 (TCGA-BP-5177.069EF9C0-FE81-4A2B-8943-7550AD0EEDA0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).